Somatic mutation profile of tumor specimen TARGET-20-PASYTG-09A (aliquot TARGET-20-PASYTG-09A-01D) from TARGET case TARGET-20-PASYTG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.9 years (6,169 days).
Specimen TARGET-20-PASYTG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f09dfcd-9e79-4d1d-86ea-ad6217e3f29e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASYTG-14A (Bone Marrow Normal), aliquot TARGET-20-PASYTG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e517efae-696a-42a7-a6e1-db82815dc509

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.676dup p.S226Ffs*17 | Frame Shift Ins (INS) | VAF 43/225 reads (19%) | catalogued as CI1111467; called by mutect2, pindel, varscan2
- GSE1 | c.427-2A>G p.X143_splice | Splice Site (SNP) | VAF 21/26 reads (81%) | called by muse, varscan2
